MMRF case MMRF_1753 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c5ef6c5d-ca25-4975-aa27-0a21b3dc0cf7

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 101 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.7 years (23,629 days); ISS stage: I; Days to last known disease status: 101 days; Days to last follow up: 101 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 101 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 101.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 36.5 mg/dL; Immunoglobulin G 8.07 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 1.5 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.65 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.12 mmol/L; C-Reactive Protein 0 mg/dL.
- Day 81 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 22.9 mg/dL; Immunoglobulin G 1 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day -5: Weight: 72 kg; Height: 171 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_1753_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1753_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
